FM case AD15490 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/920006bf-f4ad-42c9-bd15-1904a4d383d0

Female, 59.7 years: Solid pseudopapillary tumor (ICD-O-3 8452/1) of the pancreas; metastasis. Tumor nuclei on the sequenced sample's slide: 33% (pathologist estimate recorded by GDC). Sample type: Metastatic.
